Gene-level copy-number profile of tumor specimen TCGA-AG-A032-01A from TCGA case TCGA-AG-A032, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.1 years (24,865 days).
Specimen TCGA-AG-A032-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.04186ba9-f18d-47f1-b3fd-2495c69b2e2d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A032-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/45225fe2-e035-4b9c-8855-f1da193472e3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 749; copy number 2: 9,968; copy number 3: 23,579; copy number 4: 20,346; copy number 5: 2,581; copy number 6: 121; copy number 7: 144; copy number 8: 2,331.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AG-A032-01): tumor purity 0.69, ploidy 3.54, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,475 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–22,276,526, 116 genes, copy number 7 (broad region; genes not listed).
- chr13:23,328,826–114,337,626, 1,256 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr16:7,614,230–8,112,756, 3 genes, copy number 8: AC005774.2, AC005774.1, AC093515.1.
- chr20:18,567,347–64,313,132, 1,100 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 217. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
